Gene-level copy-number profile of specimen HCM-SANG-0310-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0310-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0310-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 60dbb1ba-309f-4250-a6bd-a6008295461e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0310-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,721 have no estimate.
https://portal.gdc.cancer.gov/files/9f4b7296-89c3-4af6-9be3-c3f3213b813e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 512; copy number 1: 2,181; copy number 2: 35,613; copy number 3: 14,133; copy number 4: 5,027; copy number 5: 1,110; copy number 6: 71; copy number 7: 219; copy number 8: 3; copy number 9: 3; copy number 10: 4; copy number 11: 9; copy number 12: 2; copy number 18: 2; copy number 20: 3; copy number 31: 10.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,530,287, 1 gene: HLA-DRB5.
- chr6:32,578,769–32,589,848, 1 gene: HLA-DRB1.
- chr20:15,280,764–15,280,873, 1 gene (within-gene range 0–3): RNA5SP475.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,436 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:120,150,898–121,580,524, 39 genes, copy number 6: SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, LINC00623, RNVU1-4, AC241377.4, AC241377.2, U1, AC241377.1, FCGR1B, AC244453.3, AC244453.2, H2BP1, AC244453.1, H3P4, RPL22P6, FAM72B, SRGAP2C, AC243994.1, SRGAP2-AS1, LINC02798, AL592494.1, MTIF2P1, AL592494.2, EMBP1, LINC01691.
- chr1:144,592,868–155,087,538, 468 genes, copy number 5–7 (broad region; genes not listed).
- chr1:227,393,554–232,041,272, 151 genes, copy number 5–7 (broad region; genes not listed).
- chr3:129,087,575–129,335,074, 14 genes, copy number 5–6 (within-gene range 3–6): ISY1-RAB43, AC108673.2, ISY1, AC108673.3, CNBP, RPS27P12, COPG1, MIR6826, AC137695.3, HMCES, H1-10, H1-10-AS1, NUP210P3, AC137695.1.
- chr5:58,198–11,904,446, 233 genes, copy number 5 (broad region; genes not listed).
- chr5:40,240,167–42,729,519, 31 genes, copy number 5–12: LINC00604, RNU1-150P, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1.
- chr7:7,293,508–7,293,880, 1 gene, copy number 6: AC079448.1.
- chr7:57,770,619–57,837,046, 13 genes, copy number 7: AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13.
- chr8:114,791,653–137,105,458, 280 genes, copy number 5–7 (broad region; genes not listed).
- chr12:38,078,529–38,167,631, 6 genes, copy number 6: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359.
- chr13:29,764,371–31,162,388, 36 genes, copy number 5: UBL3, Metazoa_SRP, TIMM8BP1, LINC00297, LINC00572, LINC00544, AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1.
- chr13:43,823,909–44,256,596, 14 genes, copy number 5: CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1, LINC00390, SMIM2-AS1, SMIM2, SMIM2-IT1, AL589745.2, MIR8079, AL589745.1.
- chr13:57,140,918–57,204,799, 7 genes, copy number 6: PRR20A, PRR20C, PRR20B, PRR20D, PRR20E, PRR20FP, MTCO2P3.
- chr16:18,781,295–19,718,235, 34 genes, copy number 5 (within-gene range 3–5): RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1.
- chr16:29,038,655–29,331,304, 11 genes, copy number 5 (within-gene range 4–5): NPIPB10P, AC009093.3, RRN3P2, AC009093.9, AC009093.8, AC009093.10, AC009093.2, AC009093.7, AC009093.1, AC009093.5, AC009093.4.
- chr16:77,433,382–78,066,761, 12 genes, copy number 5 (within-gene range 4–5): AC025284.1, LINC02131, AC092724.1, NUDT7, AC092134.1, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.
- chr18:22,586,465–23,672,748, 21 genes, copy number 5–7: RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1, TMEM241, AC011731.1, RIOK3, Y_RNA, AC026634.1, RMC1, NPC1, Y_RNA, ANKRD29, RPS10P27.
- chr19:27,681,072–31,349,436, 64 genes, copy number 5–31 (within-gene range 3–31) (broad region; genes not listed).
- chr20:37,178,410–37,241,619, 1 gene, copy number 5 (within-gene range 3–5): RPN2.

Autosomal genes at a single copy (total copy number 1): 1,775. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
